Gene-level copy-number profile of tumor specimen TCGA-2F-A9KW-01A from TCGA case TCGA-2F-A9KW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.6 years (24,703 days).
Specimen TCGA-2F-A9KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6f97e549-edc2-4014-b7aa-0f7b7defa481.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2F-A9KW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 843 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dfaa205e-3221-48c8-8ecf-c12cd2c62f14

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 362; copy number 2: 9,072; copy number 3: 12,234; copy number 4: 31,564; copy number 5: 1,132; copy number 6: 3,054; copy number 7: 419; copy number 8: 212; copy number 9: 79; copy number 10: 1,485; copy number 11: 14; copy number 12: 3; copy number 13: 9; copy number 16: 26; copy number 17: 11; copy number 19: 52; copy number 24: 1; copy number 25: 22; copy number 26: 6; copy number 32: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2F-A9KW-01A-11D-A38F-01): tumor purity 0.58, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,806,292–21,176,888, 1 gene (within-gene range 0–2): EIF4G3.
- chr1:20,988,314–21,073,753, 3 genes: MIR1256, RPS15AP6, AL627311.1.
- chr2:174,171,891–174,172,725, 1 gene: AC013467.1.
- chr16:3,930,806–3,950,586, 1 gene: LINC02861.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 302 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:100,509,752–101,224,573, 25 genes, copy number 13–25 (within-gene range 6–25): ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2.
- chr12:58,872,149–59,436,874, 8 genes, copy number 10–24 (within-gene range 7–24): LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P.
- chr12:62,139,999–62,622,213, 13 genes, copy number 11–19: AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2.
- chr12:63,623,788–63,795,718, 1 gene, copy number 19 (within-gene range 7–19): AC084357.2.
- chr12:63,682,523–64,990,646, 45 genes, copy number 19 (within-gene range 4–19): AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P.
- chr12:66,275,940–67,978,387, 23 genes, copy number 25–32: PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:73,820,315–74,402,600, 1 gene, copy number 26 (within-gene range 4–26): LINC02882.
- chr12:74,039,024–74,293,096, 5 genes, copy number 26: LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:79,773,563–80,380,879, 11 genes, copy number 17: PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261.
- chr12:108,858,932–109,021,068, 3 genes, copy number 12 (within-gene range 2–15): DAO, SVOP, RNU6-361P.
- chr12:109,477,402–112,418,838, 88 genes, copy number 10–16 (within-gene range 2–16) (broad region; genes not listed).
- chr17:37,798,894–39,053,205, 56 genes, copy number 9: AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 9 (within-gene range 4–9): TSHZ2.
- chr20:53,168,643–54,651,169, 22 genes, copy number 9: AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
